Somatic mutation profile of tumor specimen 0DH5VV from CCDI case PBBUFD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,036 days).
Specimen 0DH5VV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f000e78e-da83-490a-b419-a18176219e32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5UD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f0228e3-67b4-4a8d-be0b-16de6d6f4d23

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, Silent 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4051G>T p.V1351F (on ENST00000272895 / NM_173076.3; = p.V1033F on NM_015657.3) | Missense Mutation (SNP) | VAF 116/737 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as CD150426; called by muse, mutect2, varscan2
- CST9 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs150522660, COSV65402678; called by muse, mutect2, varscan2
- DMGDH | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 215/794 reads (27%) | catalogued as rs199723565; called by muse, mutect2
- OLFML3 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 133/427 reads (31%) | catalogued as rs1309175315; called by muse, mutect2, varscan2
- NTN4 | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZZEF1 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ADGRF4 | c.1197A>G p.K399= | Silent (SNP) | VAF 19/486 reads (4%) | called by muse, mutect2
- CFAP54 | c.927C>T p.A309= | Silent (SNP) | VAF 98/657 reads (15%) | catalogued as rs1014295159; called by muse, mutect2, varscan2
- ASIC2 | c.556-179591A>G | Intron (SNP) | VAF 12/261 reads (5%) | called by muse, mutect2
- NPAP1L | n.796C>T | RNA (SNP) | VAF 55/442 reads (12%) | called by muse, mutect2
